Somatic mutation profile of tumor specimen TARGET-10-PANVKH-09A (aliquot TARGET-10-PANVKH-09A-01D) from TARGET case TARGET-10-PANVKH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,624 days).
Specimen TARGET-10-PANVKH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 599be9f0-b098-450f-95f5-c0e63176ba35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVKH-10A (Blood Derived Normal), aliquot TARGET-10-PANVKH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c91ba42-6dc6-4895-83ea-672d1fdb9024

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 4, Silent 2, RNA 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 33/124 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ADGRG4 | c.7634G>A p.R2545H | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV54957269, COSV54967489; called by muse, mutect2, varscan2
- ANKRD27 | c.705+5G>T | Splice Region (SNP) | VAF 22/142 reads (15%) | catalogued as rs1568412110; called by muse, mutect2, varscan2
- DCLRE1A | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1258697452; called by muse, mutect2, varscan2
- KRT4 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as rs866940463, COSV53406692; called by muse, mutect2, varscan2
- RAB35 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | catalogued as COSV99984519; called by muse, mutect2, varscan2
- ZNF845 | c.157T>G p.C53G | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.13); called by muse, mutect2
- NTF3 | c.306G>A p.P102= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV58417625; called by muse, mutect2, varscan2
- SPIN4 | c.204C>T p.S68= | Silent (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.3172+56G>A | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- OR4C50P | n.85T>C | RNA (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- PSIP1 | c.977+85C>T | Intron (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- RSRC2 | c.207+837G>A | Intron (SNP) | VAF 7/45 reads (16%) | catalogued as rs755039151; called by muse, mutect2, varscan2
- THSD7A | c.4591-67A>T | Intron (SNP) | VAF 18/42 reads (43%) | catalogued as COSV101349198; called by muse, mutect2, varscan2
